Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9E9, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9E9-01A (Primary Tumor).

Date of surgery :

Left eye enucleation

Macroscopy

The eyeball measures 25 mm and the optic nerve 5 mm. Samples have been made for cryo preservation .The specimen has been then included entirely.

Microscopy

The eyeball is occupied by a tumor proliferation which morphologic features are those of a fusiform cell melanoma.. The lesion is loaded with melanin pigment. The mitotic index is low with 1mitosis out of 10 high 400 magnification fields. The lesion infiltrates the internal third of the sclera. There is no extra scleral extension. The tumor proliferation is distant from the internal emergence of the optic nerve. The optic foramen, the pre and post laminar section, the cut end and the meningeal sheaths are free of tumor. The iris, the ciliary body and the anterior chamber are free of tumor.

Conclusion

Choroidal melanoma with fusiform cells

Size of the lesion: 15 mm

Low mitotic activity

Optic nerve (optic foramen, per and post laminar sections), meningeal sheaths and cut end of optic nerve free of tumor

The iris, the ciliary body and the anterior chamber are free of tumor.

ICD O-3
Melanoma, spindle cell 8772/3
Site @ Choroid C69.3
J. 3/10/14

Criteria	hw 12/30/13	Yes	No
Region is Discrepancy			✓
Non Malignancy History			✓
Qualifying criteria Primary Tumor			
Site is final	3/10/14	Discrepancy	
Review or Initials	3/10/14	Discrepancy	

Source: NCI Genomic Data Commons file 9a9c06a3-fe1b-4bd7-b286-3aeec2b69167 (TCGA-V4-A9E9.C8E6E160-2B5D-466D-8C44-42516303F5A9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).